Gene-level copy-number profile of tumor specimen HCM-BROD-0650-C56-06A from HCMI case HCM-BROD-0650-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; Tumor grade: High Grade; Age at diagnosis: 67.2 years (24,542 days).
Specimen HCM-BROD-0650-C56-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file aebeb585-66f3-44d5-92a2-f08012453dc1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0650-C56-12A (saliva); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/68bc4f4d-baef-4599-9c87-8d4d29f24a3c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 5,514; copy number 2: 21,879; copy number 3: 24,728; copy number 4: 4,935; copy number 5: 1,083; copy number 6: 165; copy number 7: 23; copy number 9: 48.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:42,213,841–42,569,353, 9 genes: AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1.
- chr17:45,506,741–45,588,379, 9 genes: LRRC37A4P, Metazoa_SRP, AC091132.3, AC091132.1, AC091132.4, AC091132.5, RDM1P1, DND1P1, AC126544.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 71 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:178,960,121–182,536,772, 71 genes, copy number 7–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,336. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
